TCGA case TCGA-ET-A3BX — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8a02f305-6fd8-4908-bc19-06babf028b5b

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 24 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 24.1 years (8,791 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1a; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,596 days (4.4 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Extrathyroid extension: Minimal (T3); Lymph nodes positive: 1; Lymph nodes tested: 4; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 5; Tumor width measurement: 5.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation, External Beam.

Follow-up (4 entries)
- Days to follow up: 137 days; Disease response: Tumor Free.
- Days to follow up: 229 days; Disease response: Tumor Free.
- Days to follow up: 1,596 days (4.4 years); Disease response: Tumor Free.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ET-A3BX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 410 mg.
  Slide TCGA-ET-A3BX-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-ET-A3BX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ET-A3BX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Left lobe; Lymph nodes preop imaging: No; Lymph nodes examined: Yes; Genotypic analysis detected: No.
- Neoplasm dimension: Tumor size width: 5.0; Tumor size width: 4.0.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,596 days; disease-specific survival: no event (censored), 1,596 days; disease-free interval: no event (censored), 1,596 days; progression-free interval: no event (censored), 1,596 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ET-A3BX-01A-11D-A19I-01): tumor purity 0.77, ploidy 2, whole-genome doublings 0.
